Somatic mutation profile of tumor specimen MMRF_2468_1_BM_CD138pos (aliquot MMRF_2468_1_BM_CD138pos_T1_KHS5U_K15184) from MMRF case MMRF_2468, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.1 years (21,966 days).
Specimen MMRF_2468_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7e8d9d2-5e2a-4dab-b404-7ef2b44da0a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2468_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2468_1_PB_WBC_C3_KHS5U_K15183; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33ef520e-a3a0-4e1c-bf1b-84400e0f3170

The open-access MAF lists 70 somatic variants for this specimen: 31 protein-altering or splice-affecting, 10 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, 3'UTR 19, Silent 10, Intron 5, 5'UTR 4, Nonsense Mutation 1, 3'Flank 1, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATXN7L2 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.62); catalogued as rs751983839; called by muse, mutect2, varscan2
- CFAP46 | c.6791G>A p.R2264K | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.02); catalogued as COSV99585176; called by muse, mutect2, varscan2
- ID3 | c.300G>C p.Q100H | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV104424113, COSV65801413; called by muse, mutect2, varscan2
- MAP3K4 | c.263C>G p.T88R | Missense Mutation (SNP) | VAF 70/240 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.544); catalogued as rs1160901243; called by muse, mutect2, varscan2
- NFKBIA | c.371del p.P124Qfs*40 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | catalogued as COSV53751777; called by mutect2, pindel, varscan2
- PRRC2C | c.3860A>G p.K1287R (on ENST00000367742; = p.K1285R on NM_015172.4) | Missense Mutation (SNP) | VAF 72/301 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs144140956; called by muse, mutect2, varscan2
- RPL5 | c.47dup p.Y16* | Nonsense Mutation (INS) | VAF 28/91 reads (31%) | catalogued as CI086174; called by mutect2, pindel, varscan2
- SDC4 | c.266T>A p.I89N | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs770500121; called by muse, mutect2, varscan2
- SVIL | c.1237G>T p.D413Y | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.119); catalogued as COSV63448291; called by muse, varscan2
- SYT9 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs779476138, COSV59616249; called by muse, mutect2, varscan2
- ADAM8 | c.2049C>G p.S683R | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ARHGAP17 | c.2134A>C p.N712H (on ENST00000289968 / NM_001006634.3; = p.N634H on NM_018054.6) | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.123); called by muse, mutect2
- CELF5 | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DAGLB | c.383C>G p.T128R | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- DIS3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 80/137 reads (58%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAJB12 | c.175G>T p.D59Y (on ENST00000338820; = p.D25Y on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- EXOC6B | c.211C>G p.H71D | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- EXOSC2 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- FCRLB | c.905C>A p.P302Q | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.383); called by muse, mutect2
- KCNK2 | c.1133C>G p.T378S (on ENST00000444842 / NM_001017425.3; = p.T363S on NM_014217.4) | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KIAA1755 | c.2456T>C p.V819A | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- KLRK1 | c.309G>T p.W103C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MBD1 | c.1320G>C p.K440N (on ENST00000269468 / NM_001323950.1; = p.K384N on NM_002384.2) | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- MLX | c.225C>G p.D75E | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- MVB12B | c.363C>A p.D121E | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- MYO1D | c.2708A>G p.N903S | Missense Mutation (SNP) | VAF 79/171 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OCM2 | c.98C>G p.T33R | Missense Mutation (SNP) | VAF 89/274 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- OR52N1 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- OR5P3 | c.57G>T p.E19D | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TFDP3 | c.1122G>T p.Q374H | Missense Mutation (SNP) | VAF 80/120 reads (67%) | SIFT tolerated (0.2); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF536 | c.115A>T p.I39F | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- ACSF3 | c.1635G>A p.A545= | Silent (SNP) | VAF 66/174 reads (38%) | catalogued as rs1015935500, COSV100441278; called by muse, mutect2, varscan2
- DYNC2H1 | c.7113C>A p.T2371= | Silent (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- ERVV-1 | c.969T>A p.G323= | Silent (SNP) | VAF 32/191 reads (17%) | called by muse, mutect2, varscan2
- MN1 | c.1173C>T p.G391= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as rs1208411538, COSV56561251; called by muse, mutect2, varscan2
- PDK4 | c.939T>A p.T313= | Silent (SNP) | VAF 39/120 reads (33%) | called by muse, mutect2, varscan2
- RBM25 | c.810A>G p.E270= | Silent (SNP) | VAF 21/33 reads (64%) | called by muse, mutect2, varscan2
- REV1 | c.3294T>C p.P1098= | Silent (SNP) | VAF 40/136 reads (29%) | called by muse, mutect2, varscan2
- STMN2 | c.378C>T p.N126= | Silent (SNP) | VAF 39/128 reads (30%) | called by muse, mutect2, varscan2
- UBE4B | c.699T>G p.A233= | Silent (SNP) | VAF 71/201 reads (35%) | called by muse, mutect2, varscan2
- WFS1 | c.1176G>A p.Q392= | Silent (SNP) | VAF 32/354 reads (9%) | called by muse, mutect2
- AGPAT4 | c.-48T>A | 5'UTR (SNP) | VAF 13/52 reads (25%) | catalogued as rs994620750; called by muse, mutect2, varscan2
- CCR6 | c.*1641T>C | 3'UTR (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- CDC37L1 | c.*1060T>C | 3'UTR (SNP) | VAF 4/93 reads (4%) | called by muse, mutect2
- CLEC4M | c.*99G>A | 3'UTR (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- CNOT2 | c.1391+863C>T | Intron (SNP) | VAF 26/90 reads (29%) | called by muse, mutect2, varscan2
- DCAF17 | c.*305G>A | 3'UTR (SNP) | VAF 25/67 reads (37%) | called by muse, mutect2, varscan2
- DIS3 | c.*1565C>A | 3'UTR (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- EID2 | c.*174T>G | 3'UTR (SNP) | VAF 42/145 reads (29%) | called by muse, mutect2, varscan2
- EMP2 | c.*327G>A | 3'UTR (SNP) | VAF 45/149 reads (30%) | catalogued as rs890079138; called by muse, mutect2, varscan2
- ERBB4 | c.*4566G>A | 3'UTR (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
- FNDC3A | c.176-4290A>C | Intron (SNP) | VAF 114/189 reads (60%) | catalogued as COSV65696269; called by muse, varscan2
- GRM7 | c.-29G>A | 5'UTR (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- HS1BP3 | c.623+1994A>C | Intron (SNP) | VAF 71/184 reads (39%) | called by muse, mutect2, varscan2
- IST1 | c.892-10dup | Intron (INS) | VAF 55/193 reads (28%) | called by mutect2, pindel, varscan2
- JAM2 | c.*1189T>C | 3'UTR (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- MKLN1 | c.*6269A>T | 3'UTR (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2, varscan2
- NCAM2 | c.*5206G>C | 3'UTR (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
- ONECUT2 | c.*7017T>G | 3'UTR (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- OR2Z1 | c.*31G>A | 3'UTR (SNP) | VAF 17/76 reads (22%) | catalogued as rs368382184; called by muse, mutect2, varscan2
- PBRM1 | chr3:52547983 T>A | 3'Flank (SNP) | VAF 93/326 reads (29%) | catalogued as COSV56285299; called by muse, mutect2, varscan2
- PLEKHM2 | c.*4A>G | 3'UTR (SNP) | VAF 39/77 reads (51%) | called by muse, mutect2, varscan2
- PPIP5K2 | c.-376C>T | 5'UTR (SNP) | VAF 81/246 reads (33%) | called by muse, mutect2, varscan2
- PYGB | c.*1237G>C | 3'UTR (SNP) | VAF 35/107 reads (33%) | called by muse, mutect2, varscan2
- RCOR1 | c.*2661G>T | 3'UTR (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- SERP2 | c.158-1314T>A | Intron (SNP) | VAF 28/48 reads (58%) | called by muse, mutect2, varscan2
- SLAMF7 | c.*1359_*1364del | 3'UTR (DEL) | VAF 10/49 reads (20%) | called by mutect2, pindel, varscan2
- SLC6A5 | c.*1650del | 3'UTR (DEL) | VAF 18/58 reads (31%) | catalogued as rs896617242; called by mutect2, varscan2
- TMEM236 | c.-83C>A | 5'UTR (SNP) | VAF 50/150 reads (33%) | called by muse, mutect2, varscan2
- TRPC6 | c.*1127T>C | 3'UTR (SNP) | VAF 46/125 reads (37%) | called by muse, mutect2, varscan2
